Gene-level copy-number profile of tumor specimen TCGA-44-A47F-01A from TCGA case TCGA-44-A47F, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.3 years (27,122 days).
Specimen TCGA-44-A47F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.c802681e-a493-4289-8741-c2df7647c6a3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-A47F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13f42529-3477-4884-98e4-18dd56d208eb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 394; copy number 2: 6,874; copy number 3: 19,918; copy number 4: 13,841; copy number 5: 11,626; copy number 6: 2,322; copy number 7: 3,579; copy number 8: 1,260.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-A47F-01A-11D-A24C-01): tumor purity 0.41, ploidy 3.91, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,839 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7–8 (broad region; genes not listed).
- chr8:2,935,353–46,907,309, 906 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:59,557,528–145,066,685, 1,329 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
